Somatic mutation profile of tumor specimen TCGA-IG-A97I-01A (aliquot TCGA-IG-A97I-01A-11D-A387-09) from TCGA case TCGA-IG-A97I, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 58.2 years (21,271 days).
Specimen TCGA-IG-A97I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34474cde-b75a-46e6-bff5-04f4f2d4e308.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A97I-10A (Blood Derived Normal), aliquot TCGA-IG-A97I-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/13aa4dff-e2c5-4971-981f-d4e0bc8a2410

The open-access MAF lists 119 somatic variants for this specimen: 88 protein-altering or splice-affecting, 31 silent.
By variant classification: Missense Mutation 74, Silent 31, Nonsense Mutation 8, Frame Shift Del 3, Nonstop Mutation 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.5540C>T p.T1847M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371686531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C9orf135 | c.669T>A p.S223R | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs979444690, COSV65875278; called by muse, mutect2, varscan2
- CHD4 | c.5369G>A p.R1790Q (on ENST00000357008 / NM_001363606.2; = p.R1801Q on NM_001273.5) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs763955970, COSV58896903; called by muse, mutect2, varscan2
- COL11A1 | c.1697T>C p.V566A | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.062); catalogued as COSV100617379; called by muse, mutect2, varscan2
- DDX51 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as rs1218884231; called by muse, varscan2
- DGKA | c.1063A>G p.M355V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1565744103; called by muse, mutect2, varscan2
- DIS3L | c.1057G>T p.E353* (on ENST00000319212 / NM_001143688.3; = p.E270* on NM_133375.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 31/85 reads (36%) | catalogued as COSV59914734; called by muse, mutect2, varscan2
- DNAH5 | c.11416G>C p.E3806Q | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV54251961; called by muse, mutect2
- EBF1 | c.1213G>A p.A405T | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.668); catalogued as COSV58169354; called by muse, mutect2
- EML2 | c.722A>T p.K241M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV99840103; called by muse, mutect2, varscan2
- FBN3 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as rs778441811, COSV54467718; called by muse, mutect2, varscan2
- FKBP7 | c.667T>C p.*223Qext*10 | Nonstop Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as rs1455109407; called by muse, mutect2, varscan2
- GABRG2 | c.326T>A p.M109K | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV62717365; called by muse, mutect2, varscan2
- GBP5 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as rs143883598; called by muse, mutect2, varscan2
- GRXCR1 | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 21/63 reads (33%) | catalogued as rs754115014, COSV101295744, COSV67671089, COSV67674884; called by muse, mutect2, varscan2
- HCN1 | c.1924C>T p.P642S | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100302516; called by muse, mutect2, varscan2
- HEYL | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.64); PolyPhen benign (0.09); catalogued as rs762466594, COSV65722132; called by muse, mutect2, varscan2
- KAT6A | c.3614A>G p.Q1205R | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs754427391; called by muse, mutect2, varscan2
- LMBRD1 | c.40G>C p.G14R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779667411; called by muse, mutect2, varscan2
- MAP1B | c.6392C>T p.P2131L | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs747707013; called by muse, mutect2, varscan2
- MARCHF6 | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 27/70 reads (39%) | catalogued as COSV56881222; called by muse, mutect2, varscan2
- MEIS2 | c.451A>G p.I151V (on ENST00000561208 / NM_170675.5; = p.I138V on NM_002399.3) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV54938151; called by muse, mutect2, varscan2
- MMP15 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs199590044; called by muse, varscan2
- NPR1 | c.2129C>T p.A710V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.326); catalogued as COSV64117625; called by muse, mutect2, varscan2
- OCA2 | c.2244+2T>G p.X748_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as rs1338085924; called by muse, mutect2, varscan2
- OR8I2 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV56167645, COSV56170785; called by muse, mutect2, varscan2
- PARM1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.799); catalogued as rs866164431; called by muse, mutect2, varscan2
- PREPL | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.04); catalogued as COSV99576509; called by muse, mutect2, varscan2
- PTPN21 | c.1025C>A p.P342Q | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1338083268; called by muse, mutect2, varscan2
- ROBO2 | c.3629C>G p.S1210C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as rs755603547, COSV59909214; called by muse, mutect2, varscan2
- SLF2 | c.1952C>A p.S651Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV53275152, COSV53279782; called by muse, mutect2, varscan2
- SLITRK5 | c.908C>T p.T303M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs113077003; called by muse, mutect2, varscan2
- SPATA31D1 | c.547G>C p.D183H | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV61196632; called by muse, mutect2, varscan2
- SPTBN5 | c.7112G>A p.R2371Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs753634857, COSV58026363; called by muse, mutect2, varscan2
- SYT10 | c.281C>G p.T94S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99951521; called by muse, mutect2
- TENM3 | c.6010A>G p.I2004V | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.785); catalogued as rs1466377477; called by muse, mutect2, varscan2
- TESC | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs761040708, COSV100069283; called by muse, mutect2, varscan2
- TJP1 | c.4783A>G p.I1595V | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs1374195454; called by muse, mutect2, varscan2
- TTN | c.24725G>C p.R8242T (on ENST00000591111; = p.R7315T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/26 reads (42%) | PolyPhen benign (0.358); catalogued as COSV59968547; called by muse, mutect2, varscan2
- YES1 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as COSV58851374; called by muse, mutect2, varscan2
- ZNF23 | c.1151G>C p.R384T | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV61841330; called by muse, mutect2, varscan2
- ZNF343 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 15/89 reads (17%) | catalogued as rs766928129, COSV99601303; called by muse, mutect2, varscan2
- ACKR4 | c.140_164del p.F47Yfs*8 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel
- ALOX12 | c.1001C>G p.S334* | Nonsense Mutation (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- ATP13A3 | c.3202A>G p.I1068V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CEP20 | c.191A>C p.N64T | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2C18 | c.1400T>A p.I467N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- DNAH3 | c.5708A>T p.K1903I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- DNAH8 | c.5316G>T p.M1772I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.206); called by muse, mutect2
- DRGX | c.185C>G p.T62S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- FAM135A | c.3611A>C p.Q1204P (on ENST00000370479 / NM_001351599.1; = p.Q991P on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- FAT3 | c.588C>A p.Y196* | Nonsense Mutation (SNP) | VAF 8/22 reads (36%) | called by muse, mutect2, varscan2
- FLG | c.4084C>G p.Q1362E | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GRAMD1B | c.404G>A p.W135* | Nonsense Mutation (SNP) | VAF 16/30 reads (53%) | called by muse, mutect2, varscan2
- HORMAD1 | c.1124C>T p.S375F | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HSP90B1 | c.1910C>G p.S637C | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INTS2 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KDM2B | c.3614A>T p.Q1205L | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- KRT6A | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LANCL1 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MROH9 | c.886A>T p.K296* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | called by muse, mutect2, varscan2
- NCOA1 | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- NDNF | c.1498C>A p.Q500K | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- NIPBL | c.850A>T p.S284C | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- NOXO1 | c.451C>G p.L151V (on ENST00000397280 / NM_172168.3; = p.L145V on NM_144603.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2B6 | c.816G>C p.K272N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4A15 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR4K14 | c.775T>G p.Y259D | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- OR4N2 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 91/342 reads (27%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- OR6X1 | c.520C>G p.H174D | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- PADI1 | c.1319G>C p.G440A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PKHD1L1 | c.5063C>A p.S1688Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PPFIBP2 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SH3PXD2A | c.670A>T p.N224Y | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SLC16A4 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 6/79 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPATA33 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPOP | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SPTBN2 | c.6473_6474del p.L2158Rfs*130 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- SYNE1 | c.12910G>A p.E4304K (on ENST00000367255 / NM_182961.4; = p.E4233K on NM_033071.3) | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TAF7L | c.952T>C p.Y318H | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- TEKT2 | c.608T>C p.V203A | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TNKS2 | c.715_723del p.A239_D241del | In Frame Del (DEL) | VAF 24/84 reads (29%) | called by mutect2, pindel, varscan2
- TP53 | c.1170del p.D391Tfs*31 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel*, varscan2
- WASHC4 | c.1052C>A p.T351N | Missense Mutation (SNP) | VAF 31/131 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- XIRP2 | c.6302T>A p.F2101Y (on ENST00000628543; = p.F2276Y on NM_152381.6) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF578 | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- ZNF607 | c.1802C>T p.A601V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AC023055.1 | c.1353A>T p.S451= | Silent (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- ANKRD2 | c.522C>T p.A174= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs140424419; called by muse, mutect2, varscan2
- CEL | c.234G>A p.L78= (on ENST00000673714; = p.L75= on NM_001807.6) | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2, varscan2
- CHST8 | c.774C>T p.R258= | Silent (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- CLSPN | c.2457C>G p.V819= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- CYP2U1 | c.540C>T p.F180= | Silent (SNP) | VAF 13/60 reads (22%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.8488C>T p.L2830= | Silent (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- GHITM | c.84G>A p.V28= | Silent (SNP) | VAF 20/64 reads (31%) | called by muse, mutect2, varscan2
- HOXC9 | c.531G>A p.L177= | Silent (SNP) | VAF 5/19 reads (26%) | called by muse, mutect2, varscan2
- IGHG4 | c.696C>G p.P232= | Silent (SNP) | VAF 34/269 reads (13%) | called by muse, mutect2, varscan2
- IREB2 | c.2817G>A p.S939= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs144816277; called by muse, mutect2, varscan2
- KDM1A | c.1323G>A p.L441= | Silent (SNP) | VAF 21/69 reads (30%) | catalogued as rs934800721; called by muse, mutect2, varscan2
- LAMA5 | c.9621C>T p.Y3207= | Silent (SNP) | VAF 40/167 reads (24%) | called by muse, mutect2, varscan2
- LRCH1 | c.381G>T p.L127= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV100243194; called by muse, mutect2, varscan2
- MACC1 | c.498C>T p.H166= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs146810957; called by muse, mutect2, varscan2
- MAGEA4 | c.369C>A p.R123= | Silent (SNP) | VAF 39/53 reads (74%) | called by muse, mutect2, varscan2
- MAP3K15 | c.2940A>G p.P980= | Silent (SNP) | VAF 19/24 reads (79%) | called by muse, mutect2, varscan2
- MGA | c.2800C>T p.L934= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV54963796; called by muse, mutect2, varscan2
- MPO | c.367C>T p.L123= | Silent (SNP) | VAF 19/52 reads (37%) | called by muse, mutect2, varscan2
- PID1 | c.696C>A p.I232= (on ENST00000354069 / NM_001330156.1; = p.I230= on NM_017933.5) | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV62475780; called by muse, mutect2, varscan2
- PIK3C3 | c.2289A>T p.G763= | Silent (SNP) | VAF 38/64 reads (59%) | called by muse, mutect2, varscan2
- PLEKHA7 | c.642C>T p.Y214= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs367816429; called by muse, mutect2, varscan2
- PTK2 | c.1128G>A p.L376= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as rs748726361; called by muse, mutect2, varscan2
- RIMS1 | c.4407C>T p.S1469= | Silent (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- SDHAF2 | c.408C>G p.V136= | Silent (SNP) | VAF 19/64 reads (30%) | called by muse, mutect2, varscan2
- SPTAN1 | c.6237T>G p.L2079= | Silent (SNP) | VAF 30/57 reads (53%) | called by muse, mutect2, varscan2
- TAS2R16 | c.837C>T p.S279= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs868847996, COSV50797818; called by muse, mutect2, varscan2
- TMPRSS11B | c.660A>G p.L220= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- TRIM62 | c.1371G>A p.Q457= | Silent (SNP) | VAF 12/26 reads (46%) | called by muse, mutect2, varscan2
- ZDHHC11 | c.765C>T p.L255= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs1258312079; called by muse, mutect2, varscan2
- ZNRF4 | c.754C>T p.L252= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as rs769289392; called by muse, mutect2, varscan2
